Somatic mutation profile of tumor specimen TCGA-QT-A5XP-01A (aliquot TCGA-QT-A5XP-01A-11D-A35D-08) from TCGA case TCGA-QT-A5XP, project TCGA-PCPG (Pheochromocytoma and Paraganglioma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Pheochromocytoma, malignant; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 57.7 years (21,072 days).
Specimen TCGA-QT-A5XP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6436e311-c7b5-4adf-a92c-95cbdbb88bd8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-QT-A5XP-10A (Blood Derived Normal), aliquot TCGA-QT-A5XP-10A-01D-A35B-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/030d6dc3-0552-4b75-af3f-455dc8e4de2a

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 1, Frame Shift Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TPI1 | c.110C>T p.A37V | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.009); catalogued as rs1555131475; called by muse, mutect2
- DENND4A | c.5335C>T p.P1779S | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LAMC3 | c.1737del p.T580Qfs*7 | Frame Shift Del (DEL) | VAF 6/36 reads (17%) | called by mutect2, pindel, varscan2
- PIM2 | c.61+1G>A p.X21_splice | Splice Site (SNP) | VAF 4/25 reads (16%) | called by muse, mutect2, varscan2
- TRIO | c.443C>G p.S148C | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZFHX3 | c.8354T>G p.L2785R | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.641); called by muse, mutect2, varscan2
- CUL4B | c.1845G>T p.L615= | Silent (SNP) | VAF 18/150 reads (12%) | called by muse, mutect2, varscan2
- PLEKHG1 | c.4086T>A p.S1362= | Silent (SNP) | VAF 28/83 reads (34%) | called by muse, mutect2, varscan2
- RAP1GAP | c.-149+4015A>G | Intron (SNP) | VAF 4/16 reads (25%) | called by muse, mutect2
